Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NY-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3
adenocarcinoma, endometrioid, Nos 8380/3
Site: endometrium C54.1 2/24/11 *lu*

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, bilateral ovaries, and fallopian tubes;
hysterectomy and
bilateral salpingo-oophorectomy:
Endometrial adenocarcinoma, endometrioid type, FIGO grade
3 (of 3)
is identified forming a mass (6.0 x 3.5 x 2.2 cm)
circumferentially
involving the endometrial cavity and the lower uterine
segment. The
tumor invades 1.7 cm into the myometrium (total myometrial
thickness, 2.0 cm). The tumor does not involve the
endocervix.
Lymphovascular space invasion is identified. The margins
are
negative for tumor. There are multiple (6) intramural
leiomyomas
(ranging in size from 0.5 cm to 2.4 cm in greatest
dimension) in the
myometrium. The bilateral ovaries and fallopian tubes are
uninvolved.
- B. Lymph nodes, right pelvic, lymphadenectomy: Multiple
(13) right
pelvic lymph nodes are negative for tumor.
- C. Lymph nodes, left pelvic, lymphadenectomy: Multiple
(14) left
pelvic lymph nodes are negative for tumor.
- D. Lymph nodes, right para-aortic, lymphadenectomy:
Multiple (4)
right para-aortic lymph nodes are negative for tumor.
- E. Lymph nodes, left para-aortic, lymphadenectomy:
Multiple (6)
left para-aortic lymph nodes are negative for tumor.

[page 2 of 3]
With available surgical material [AJCC pT1bN0] (7th edition, 2010).

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 220.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa has focal fibrous adhesions. There is a 6.0 x 3.5 x 2.2 cm exophytic polypoid soft tan circumferential mass in the body and lower uterine segment of the endometrial cavity grossly invading 1.7 cm. The myometrial thickness is 2.0 cm. There are multiple (6) intramural leiomyomas (ranging in size from 0.5 cm to 2.4 cm in greatest dimension). There is a 2.5 x 2.0 x 1.7 cm right ovary with a smooth outer surface and a solid cut surface with a 7.5 x 0.6 cm right fallopian tube which is unremarkable. There is a 2.7 x 2.0 x 1.5 cm left ovary with a smooth outer surface and a solid cut surface with a 7.4 x 0.6 cm left fallopian tube which is unremarkable. Representative sections submitted.

[page 3 of 3]
B. Received fresh labeled "right pelvic lymph nodes" is a 4.5 x 4.0 x 1.2 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 7.5 x 7.0 x 1.2 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

D. Received fresh labeled "right para-aortic lymph nodes" is a 1.2 x 1.0 x 0.9 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

E. Received fresh labeled "left para-aortic lymph nodes" is a 1.2 x 1.0 x 0.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

Source: NCI Genomic Data Commons file bead6a47-5baa-447d-b230-35ddf09bc609 (TCGA-D1-A1NY.8F963009-F6C3-4F45-B714-0E96F5D5E526.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).